CCDI case PBCCYX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/3e809940-fdd5-475a-a2b5-8c20e264e8d0

Demographics
Sex at birth: male.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Bones of skull and face and associated joints; Age at diagnosis: 6.3 years (2,300 days).

Biospecimens (3 samples)
- Sample 0DOXG1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOXGO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DOXGZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
